Gene-level copy-number profile of tumor specimen TCGA-XM-AAZ1-01A from TCGA case TCGA-XM-AAZ1, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 42.1 years (15,383 days).
Specimen TCGA-XM-AAZ1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.098c8e42-7212-41ef-8029-afb0be8585e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XM-AAZ1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-XM-AAZ1-01A|TCGA-XM-AAZ1-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a050753b-2320-4369-ac6e-fdf2ba843614

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,309; copy number 2: 44,024; copy number 3: 10,848; copy number 4: 2,625.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XM-AAZ1-01A-11D-A422-01): tumor purity 0.65, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,318,861, 9 genes (within-gene range 0–2): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
